Somatic mutation profile of tumor specimen RC-B5DD-TTP1-A (aliquot RC-B5DD-TTP1-A-1-1-D-A93N-47) from RC case RC-B5DD, project RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL). Sex at birth: male; Vital status: Dead; Primary diagnosis: Extranodal NK/T-cell lymphoma, nasal type; Tissue or organ of origin: Unknown primary site; Age at diagnosis: 81.4 years (29,732 days).
Specimen RC-B5DD-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2e9a1882-0953-4939-b332-3cedb37adc8f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen RC-B5DD-NB1-A (Granulocytes; tissue type Normal), aliquot RC-B5DD-NB1-A-1-0-D-A93N-47; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b8785a0c-6c65-4235-b7bd-47faea01e9d1

The open-access MAF lists 79 somatic variants for this specimen: 57 protein-altering or splice-affecting, 17 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 17, Nonsense Mutation 6, 3'UTR 2, Intron 2, Frame Shift Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC2 | c.3447G>C p.R1149S | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV64987172; called by muse, mutect2, varscan2
- BCHE | c.1729C>T p.R577C | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs751164424, COSV52253716; called by muse, mutect2
- BNIP3L | c.507G>A p.M169I | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.1); catalogued as COSV66078267; called by muse, mutect2, varscan2
- CASKIN2 | c.406C>T p.Q136* | Nonsense Mutation (SNP) | VAF 16/63 reads (25%) | catalogued as COSV100395237; called by muse, mutect2, varscan2
- CEP85L | c.2413C>T p.Q805* | Nonsense Mutation (SNP) | VAF 28/88 reads (32%) | catalogued as COSV63823442; called by muse, mutect2, varscan2
- CHST2 | c.1022G>A p.R341Q | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1156685176, COSV58885172; called by muse, mutect2, varscan2
- DDR2 | c.2003G>A p.R668H | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as rs754868982, COSV63370876; called by muse, mutect2, varscan2
- EPHB1 | c.1102C>G p.R368G | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT tolerated (0.77); PolyPhen probably damaging (0.998); catalogued as rs576710309, COSV101213156, COSV67655893; called by muse, mutect2, varscan2
- GALK2 | c.1024G>A p.V342M | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs774458462; called by muse, mutect2, varscan2
- IGKV3-15 | c.169C>T p.Q57* | Nonsense Mutation (SNP) | VAF 52/218 reads (24%) | catalogued as rs772980261; called by muse, mutect2, varscan2
- KCTD16 | c.857C>A p.S286* | Nonsense Mutation (SNP) | VAF 21/77 reads (27%) | catalogued as COSV72579580; called by muse, mutect2, varscan2
- KIAA1217 | c.2552G>A p.S851N | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs781512216, COSV56823325; called by muse, mutect2, varscan2
- LINGO2 | c.1037C>T p.A346V | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.297); catalogued as rs775232627, COSV58061899; called by muse, mutect2, varscan2
- MUC6 | c.3427G>A p.G1143S | Missense Mutation (SNP) | VAF 49/177 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.026); catalogued as rs1322615201; called by muse, mutect2, varscan2
- PITPNM2 | c.2326C>T p.R776C | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs777853059, COSV54895884; called by muse, mutect2, varscan2
- PLCH1 | c.2857C>G p.Q953E (on ENST00000340059 / NM_001130960.2; = p.Q945E on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as COSV100398241; called by muse, mutect2, varscan2
- RAI2 | c.647C>T p.P216L | Missense Mutation (SNP) | VAF 34/47 reads (72%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV58963573; called by muse, mutect2, varscan2
- RYR1 | c.9862G>A p.G3288R | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769054388; called by muse, mutect2, varscan2
- SOX5 | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.093); catalogued as rs1308991771; called by muse, mutect2, varscan2
- SYT10 | c.1014G>C p.L338F | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.027); catalogued as rs369857680; called by muse, mutect2, varscan2
- TDRD1 | c.2986G>A p.A996T | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); catalogued as rs199536592, COSV52592509, COSV52593665; called by muse, mutect2, varscan2
- TTC29 | c.476G>A p.R159K | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.093); catalogued as COSV57287836; called by muse, mutect2
- UBA3 | c.893C>T p.T298M | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs201471678; called by muse, mutect2, varscan2
- WLS | c.926C>T p.A309V | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as rs764615459, COSV52040347; called by muse, mutect2, varscan2
- XDH | c.2698C>T p.R900W | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.671); catalogued as rs763704314; called by muse, mutect2, varscan2
- AMER3 | c.923G>T p.R308M | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- ANKRD33B | c.265C>T p.L89F | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- CCDC170 | c.1503A>T p.E501D | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.47); called by muse, mutect2, varscan2
- CD79A | c.472G>T p.V158L | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- CSE1L | c.2840T>G p.V947G | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.362); called by muse, mutect2, varscan2
- DDX1 | c.1402G>T p.D468Y | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- DEUP1 | c.1178T>C p.L393P | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DSEL | c.1708T>C p.Y570H | Missense Mutation (SNP) | VAF 48/146 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ESYT2 | c.2150A>G p.E717G (on ENST00000613624; = p.E641G on NM_020728.3) | Missense Mutation (SNP) | VAF 77/174 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FPR3 | c.148G>T p.V50L | Missense Mutation (SNP) | VAF 43/141 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- HLA-B | c.916_920del p.V306Hfs*26 | Frame Shift Del (DEL) | VAF 30/117 reads (26%) | called by mutect2, pindel, varscan2
- HPN | c.1215G>T p.K405N | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- KALRN | c.4100A>G p.D1367G | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LRP2 | c.4034C>A p.S1345Y | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LRRC49 | c.1825A>T p.T609S | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.58); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- MYBPC1 | c.3282G>T p.R1094S (on ENST00000550270 / NM_206820.2; = p.R1101S on NM_002465.4) | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MYOM2 | c.1684C>A p.Q562K | Missense Mutation (SNP) | VAF 68/176 reads (39%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.485); called by muse, mutect2, varscan2
- NCBP3 | c.1690G>T p.D564Y | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- NOD2 | c.34G>C p.E12Q | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- OR52M1 | c.287T>C p.L96P | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); called by muse, mutect2
- OR7C2 | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- POT1 | c.551G>A p.W184* | Nonsense Mutation (SNP) | VAF 18/113 reads (16%) | called by muse, mutect2, varscan2
- POTEH | c.1045G>A p.A349T | Missense Mutation (SNP) | VAF 27/228 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- ROBO2 | c.2882G>A p.G961E | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated (0.9); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- RYR1 | c.5032A>T p.N1678Y | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- SCML1 | c.193T>C p.C65R (on ENST00000380041 / NM_001037540.3; = p.C38R on NM_006746.6) | Missense Mutation (SNP) | VAF 23/35 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SEPSECS | c.1354A>T p.K452* | Nonsense Mutation (SNP) | VAF 32/97 reads (33%) | called by muse, mutect2, varscan2
- SETD1A | c.1882C>T p.H628Y | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- SI | c.2604G>C p.Q868H | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- SLC39A6 | c.820C>T p.H274Y | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- SLC44A3 | c.1453C>G p.L485V (on ENST00000271227 / NM_001114106.3; = p.L437V on NM_152369.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- TEK | c.1015C>A p.Q339K | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- ABCD3 | c.372A>G p.R124= | Silent (SNP) | VAF 31/91 reads (34%) | called by muse, mutect2, varscan2
- APBA1 | c.336C>T p.P112= | Silent (SNP) | VAF 35/122 reads (29%) | catalogued as rs142271429; called by muse, mutect2, varscan2
- C19orf57 | c.36G>A p.E12= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as rs143506230; called by muse, mutect2, varscan2
- KCNK2 | c.108G>A p.S36= (on ENST00000444842 / NM_001017425.3; = p.S21= on NM_014217.4) | Silent (SNP) | VAF 35/82 reads (43%) | catalogued as rs1481663513, COSV67204836; called by muse, mutect2, varscan2
- KNTC1 | c.654T>C p.V218= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as rs1221774390; called by muse, mutect2, varscan2
- LYRM2 | c.258C>T p.S86= | Silent (SNP) | VAF 37/82 reads (45%) | called by muse, mutect2, varscan2
- PCDHB4 | c.1551G>T p.S517= | Silent (SNP) | VAF 83/218 reads (38%) | catalogued as COSV52022371, COSV52022408; called by muse, mutect2, varscan2
- PECAM1 | c.2094T>G p.A698= | Silent (SNP) | VAF 22/72 reads (31%) | called by muse, mutect2, varscan2
- PRUNE2 | c.6648A>T p.P2216= | Silent (SNP) | VAF 32/88 reads (36%) | called by muse, mutect2, varscan2
- QRSL1 | c.1296G>A p.E432= | Silent (SNP) | VAF 37/100 reads (37%) | catalogued as rs899494091; called by muse, mutect2, varscan2
- SASH1 | c.3219C>T p.H1073= | Silent (SNP) | VAF 39/114 reads (34%) | catalogued as rs765382768, COSV66561779; called by muse, mutect2, varscan2
- SPATA31D1 | c.1683A>G p.L561= | Silent (SNP) | VAF 69/176 reads (39%) | catalogued as rs1211216282; called by muse, mutect2, varscan2
- SPIN4 | c.432A>C p.R144= | Silent (SNP) | VAF 48/74 reads (65%) | called by muse, mutect2, varscan2
- TCN2 | c.966C>A p.T322= | Silent (SNP) | VAF 23/70 reads (33%) | called by muse, mutect2, varscan2
- TFAP2E | c.534C>T p.S178= | Silent (SNP) | VAF 20/74 reads (27%) | called by muse, mutect2, varscan2
- VWA5B1 | c.309C>T p.D103= | Silent (SNP) | VAF 19/61 reads (31%) | catalogued as rs992523891, COSV57057261; called by muse, mutect2, varscan2
- WDFY4 | c.7329G>A p.P2443= | Silent (SNP) | VAF 23/65 reads (35%) | catalogued as rs780326609, COSV55437110; called by muse, mutect2, varscan2
- SLAMF8 | c.*1854A>G | 3'UTR (SNP) | VAF 25/89 reads (28%) | called by muse, mutect2, varscan2
- SLC12A5 | chr20:46058713 C>T | 3'Flank (SNP) | VAF 19/54 reads (35%) | catalogued as rs766336928; called by muse, mutect2, varscan2
- TECTB | c.940+179C>T | Intron (SNP) | VAF 20/95 reads (21%) | called by muse, mutect2, varscan2
- THBS4 | c.1892+1043C>T | Intron (SNP) | VAF 22/68 reads (32%) | called by muse, mutect2, varscan2
- ZNF99 | c.*272G>A | 3'UTR (SNP) | VAF 37/125 reads (30%) | catalogued as rs756297350, COSV68056819; called by muse, mutect2, varscan2
